Somatic mutation profile of tumor specimen TCGA-17-Z022-01A (aliquot TCGA-17-Z022-01A-01W-0746-08) from TCGA case TCGA-17-Z022, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z022-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47c43e45-c3b5-458b-9b39-a2e99a058199.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z022-11A (Solid Tissue Normal), aliquot TCGA-17-Z022-11A-01W-0746-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/182fab72-ac82-424f-86d6-200179dc5564

The open-access MAF lists 1,340 somatic variants for this specimen: 999 protein-altering or splice-affecting, 305 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 876, Silent 305, Nonsense Mutation 65, Splice Site 21, Frame Shift Del 21, Intron 16, RNA 9, Frame Shift Ins 6, Splice Region 5, Nonstop Mutation 4, 5'UTR 4, 5'Flank 4.

Variants (750 of 1,340; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA2 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867160952, COSV62003170, COSV62003780, COSV62007157; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 12/16 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SMAD4 | c.1572G>T p.W524C | Missense Mutation (SNP) | VAF 33/44 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.917); catalogued as COSV61685820, COSV61686227, COSV61686374; called by muse, mutect2, varscan2
- SQSTM1 | c.286C>T p.R96* | Nonsense Mutation (SNP) | VAF 11/12 reads (92%) | catalogued as rs886039782, CM146303, COSV62434401, COSV62434714; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 31/39 reads (79%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1567548929, COSV52662086, COSV52675732, COSV52773165, COSV52962390; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.400C>G p.Q134E | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as HM070110; called by muse, mutect2, varscan2
- ABCB11 | c.3676C>T p.R1226C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772241929, COSV55591899; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99328994; called by muse, mutect2, varscan2
- ABCB5 | c.2272G>T p.G758C (on ENST00000404938 / NM_001163941.2; = p.G313C on NM_178559.6) | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs373783857, COSV51723348, COSV99327421; called by muse, varscan2
- ABCC5 | c.3403T>C p.Y1135H | Missense Mutation (SNP) | VAF 20/29 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1297086684; called by muse, mutect2, varscan2
- ABCE1 | c.1174C>T p.L392F | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs1161417930; called by muse, mutect2, varscan2
- ACTL6B | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.929); catalogued as rs748105438, COSV50514457, COSV50514641; called by muse, mutect2, varscan2
- ACVR1 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as rs753599813; called by muse, mutect2, varscan2
- ADAM11 | c.1684G>T p.A562S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.156); catalogued as rs1312390576; called by muse, mutect2, varscan2
- ADAMDEC1 | c.4C>A p.L2M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.133); catalogued as rs1169875049; called by muse, mutect2
- ADAMTS18 | c.1118C>G p.S373C | Missense Mutation (SNP) | VAF 31/41 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51399139, COSV51420022; called by muse, mutect2, varscan2
- ADAMTS5 | c.1427C>T p.P476L | Missense Mutation (SNP) | VAF 29/42 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537732; called by muse, mutect2, varscan2
- ADARB2 | c.1964C>A p.T655N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV67182815; called by muse, varscan2
- ADGRB3 | c.2061G>T p.M687I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as rs1470554633; called by muse, mutect2, varscan2
- ADGRE3 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53730300; called by muse, mutect2, varscan2
- ADRA2C | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.734); catalogued as rs1395587788; called by muse, mutect2, varscan2
- AFAP1L1 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV57045543; called by muse, mutect2, varscan2
- AMER1 | c.1801C>G p.R601G | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.046); catalogued as COSV57659668; called by muse, mutect2, varscan2
- AMMECR1L | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV99761232; called by muse, mutect2, varscan2
- ANK2 | c.11522C>A p.P3841Q | Missense Mutation (SNP) | VAF 43/82 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs767769233, COSV52174340; called by muse, varscan2
- ANKDD1A | c.1428C>A p.N476K | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263097133; called by muse, mutect2, varscan2
- ANKFN1 | c.1028A>G p.Y343C | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1568005047; called by muse, mutect2, varscan2
- AOAH | c.929C>T p.S310F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV51742906; called by muse, mutect2, varscan2
- APPL1 | c.2075A>T p.Q692L | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs200390978; called by muse, mutect2, varscan2
- ARHGAP27 | c.2075-2A>G p.X692_splice (on ENST00000428638 / NM_001282290.1; = p.X351_splice on NM_199282.3) | Splice Site (SNP) | VAF 7/23 reads (30%) | catalogued as rs1253849503; called by muse, mutect2, varscan2
- ARHGAP36 | c.47C>A p.P16H | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV52269343; called by muse, mutect2, varscan2
- ARPIN | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 49/107 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.18); catalogued as rs777490432; called by muse, mutect2, varscan2
- ATP10D | c.3917C>T p.T1306M | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs556426025; called by muse, mutect2, varscan2
- ATP1A3 | c.2734G>C p.E912Q (on ENST00000545399 / NM_001256214.2; = p.E899Q on NM_152296.5) | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100131800; called by muse, mutect2
- ATP1A3 | c.2296G>T p.E766* (on ENST00000545399 / NM_001256214.2; = p.E753* on NM_152296.5) | Nonsense Mutation (SNP) | VAF 110/144 reads (76%) | catalogued as COSV57489864; called by muse, mutect2, varscan2
- ATP5PB | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as rs1400020387; called by muse, mutect2, varscan2
- ATP6AP1 | c.1397T>C p.L466S | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs782069740; called by muse, mutect2, varscan2
- ATRX | c.4839G>T p.L1613F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100970220; called by muse, mutect2, varscan2
- BAZ1B | c.1511G>T p.R504L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV59990830; called by muse, mutect2, varscan2
- BAZ2B | c.2008A>G p.M670V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs370150609; called by muse, mutect2, varscan2
- BMP15 | c.985C>T p.R329C | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs782375794, CM100080, COSV99399521; called by muse, mutect2, varscan2
- BRCA2 | c.6313A>T p.I2105L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.067); catalogued as COSV101203826; called by muse, mutect2
- BRINP1 | c.41T>C p.I14T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs1289647572; called by muse, mutect2, varscan2
- BSDC1 | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs1180465863; called by muse, mutect2, varscan2
- BTN2A2 | c.735G>T p.M245I | Missense Mutation (SNP) | VAF 71/167 reads (43%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1368725932; called by muse, mutect2, varscan2
- BUB1B | c.368A>G p.N123S | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs759232092; called by mutect2, varscan2
- C20orf194 | c.1775A>G p.Y592C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs751133882; called by muse, mutect2, varscan2
- C6orf118 | c.70C>A p.L24M | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.857); catalogued as COSV57816643; called by muse, mutect2, varscan2
- CABS1 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); catalogued as rs1200521439; called by muse, mutect2, varscan2
- CACNA1C | c.296G>C p.R99P | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59735896; called by muse, varscan2
- CAPN6 | c.1769A>T p.D590V | Missense Mutation (SNP) | VAF 66/123 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100136576; called by muse, mutect2, varscan2
- CASP9 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as rs1162039291; called by muse, mutect2, varscan2
- CBLN4 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.376); catalogued as rs1322710593; called by muse, mutect2, varscan2
- CCND2 | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.116); catalogued as rs780649921, COSV54221669, COSV54224637; called by muse, mutect2, varscan2
- CCR8 | c.931C>T p.L311F | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as rs200955972; called by muse, mutect2, varscan2
- CD163L1 | c.3204C>A p.S1068R | Missense Mutation (SNP) | VAF 97/146 reads (66%) | SIFT tolerated (0.32); PolyPhen benign (0.228); catalogued as COSV58011939; called by muse, mutect2, varscan2
- CD6 | c.796C>A p.R266S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as rs750247319, COSV57836126; called by muse, mutect2, varscan2
- CD8A | c.671C>A p.S224* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV52159886; called by muse, mutect2, varscan2
- CD93 | c.693C>A p.D231E | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs749366333; called by muse, mutect2, varscan2
- CDH12 | c.781G>T p.D261Y | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759364590; called by muse, varscan2
- CDH9 | c.949G>C p.D317H | Missense Mutation (SNP) | VAF 98/192 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs141440884; called by muse, mutect2, varscan2
- CDK15 | c.24G>T p.K8N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1172958647; called by muse, mutect2, varscan2
- CDRT1 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.848); catalogued as COSV100599855; called by muse, mutect2, varscan2
- CEP290 | c.3358G>T p.D1120Y | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99063709; called by muse, mutect2, varscan2
- CHST8 | c.1195C>A p.Q399K | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as rs776569880; called by muse, mutect2, varscan2
- CLCA2 | c.1156G>T p.A386S | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.492); catalogued as rs1178198260; called by muse, mutect2, varscan2
- CLEC4E | c.241C>T p.P81S | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775618534; called by muse, mutect2, varscan2
- CNTNAP4 | c.834G>T p.Q278H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1252680254; called by muse, mutect2, varscan2
- CNTNAP5 | c.2629G>A p.V877I | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV70519201; called by muse, varscan2
- CNTNAP5 | c.3232T>A p.Y1078N | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1289672419; called by muse, mutect2, varscan2
- COIL | c.854C>G p.S285C | Missense Mutation (SNP) | VAF 24/143 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs752670467; called by muse, mutect2, varscan2
- COL11A1 | c.5332G>T p.V1778L | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV62190364; called by muse, mutect2, varscan2
- COL11A1 | c.5222A>G p.E1741G | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs768596501; called by muse, mutect2, varscan2
- COL22A1 | c.4534G>T p.G1512C | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189705630; called by muse, mutect2, varscan2
- COL4A5 | c.1469C>T p.S490L | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs764543034; called by muse, varscan2
- COL6A3 | c.3100C>T p.L1034F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.475); catalogued as rs776389712; called by mutect2, varscan2
- COL7A1 | c.5134G>A p.G1712R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.986); catalogued as COSV100097798, COSV60399489; called by muse, mutect2, varscan2
- CPZ | c.268G>A p.E90K (on ENST00000360986 / NM_001014447.3; = p.E79K on NM_003652.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs761264809, COSV59923379; called by muse, mutect2, varscan2
- CRACD | c.934G>T p.E312* | Nonsense Mutation (SNP) | VAF 5/10 reads (50%) | catalogued as rs1444378185; called by muse, mutect2, varscan2
- CREB5 | c.354C>A p.S118R (on ENST00000357727 / NM_182898.4; = p.S111R on NM_004904.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.044); catalogued as rs1216425602; called by muse, varscan2
- CRMP1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200099288; called by muse, mutect2, varscan2
- CRYGA | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs766462446, COSV100378360, COSV100378675; called by muse, mutect2, varscan2
- CSMD1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); catalogued as rs773296700, COSV68190724; called by muse, mutect2, varscan2
- CSMD3 | c.10611G>T p.M3537I (on ENST00000297405 / NM_001363185.1; = p.M3368I on NM_052900.3) | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV99831444; called by muse, varscan2
- CSMD3 | c.10457C>G p.P3486R (on ENST00000297405 / NM_001363185.1; = p.P3317R on NM_052900.3) | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1326989494, COSV99837373; called by muse, mutect2, varscan2
- CSMD3 | c.1801G>A p.D601N (on ENST00000297405 / NM_001363185.1; = p.D497N on NM_052900.3) | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99852983; called by muse, varscan2
- CUL5 | c.2256G>C p.M752I | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV67609072; called by muse, mutect2, varscan2
- CYP4B1 | c.679G>T p.V227L | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs767284537; called by muse, varscan2
- CYP7B1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100042551; called by muse, mutect2, varscan2
- DAD1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1429389490, COSV51663168; called by muse, mutect2, varscan2
- DBX2 | c.845T>A p.V282D | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV104409544; called by muse, mutect2, varscan2
- DCAF12L1 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1180607542, COSV64422079; called by muse, mutect2, varscan2
- DCHS1 | c.8456A>T p.H2819L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1367055364; called by muse, mutect2, varscan2
- DCST1 | c.475C>A p.R159S | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV99792573; called by muse, mutect2
- DCT | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 229/338 reads (68%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100986289; called by muse, varscan2
- DENND2A | c.373G>C p.G125R | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1423072997; called by muse, mutect2, varscan2
- DLGAP1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1311806372, COSV59813049; called by muse, mutect2, varscan2
- DLX5 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1406598149; called by muse, mutect2, varscan2
- DMRT3 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.826); catalogued as rs750576922; called by muse, mutect2, varscan2
- DNAH11 | c.12616C>A p.L4206M | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777004813; called by muse, mutect2, varscan2
- DNAH3 | c.1431C>A p.Y477* | Nonsense Mutation (SNP) | VAF 16/63 reads (25%) | catalogued as COSV54524500; called by muse, mutect2, varscan2
- DPH6 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 37/55 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.078); catalogued as rs1444301622; called by muse, mutect2, varscan2
- DPP10 | c.2285C>T p.S762F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100062347, COSV59680781; called by muse, mutect2
- DSC1 | c.2372C>T p.S791F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs754301512; called by muse, mutect2, varscan2
- DSE | c.742A>T p.R248W | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV59062034; called by muse, mutect2, varscan2
- DSG1 | c.1433C>A p.T478K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99936049; called by muse, mutect2, varscan2
- DSPP | c.1340G>T p.S447I | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.637); catalogued as rs1322362395; called by muse, mutect2, varscan2
- DST | c.16678C>G p.Q5560E (on ENST00000361203 / NM_001374722.1; = p.Q3257E on NM_015548.5) | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as rs1172670453; called by muse, mutect2, varscan2
- DTX1 | c.969G>T p.L323F | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs1193575071; called by muse, mutect2, varscan2
- DYNC1H1 | c.12218C>T p.S4073F | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64141221; called by muse, mutect2, varscan2
- DYNC2H1 | c.11388G>C p.L3796F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.766); catalogued as rs1214797317; called by muse, mutect2, varscan2
- EBF1 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV58185070; called by muse, mutect2, varscan2
- ECT2 | c.868G>C p.E290Q (on ENST00000392692 / NM_001349098.2; = p.E259Q on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.18); catalogued as COSV99221384; called by muse, mutect2, varscan2
- EFNA3 | c.578A>G p.N193S | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.26); PolyPhen benign (0.042); catalogued as rs1160303598; called by muse, mutect2, varscan2
- EGFLAM | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 125/202 reads (62%) | catalogued as COSV59300497; called by muse, mutect2, varscan2
- EIF2B4 | c.416C>T p.S139L (on ENST00000347454 / NM_001034116.2; = p.S138L on NM_015636.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52010444, COSV99278039; called by muse, mutect2, varscan2
- EPB41L3 | c.1714G>T p.A572S | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs1461592162; called by muse, mutect2, varscan2
- EPG5 | c.5161C>G p.L1721V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56346599; called by muse, mutect2, varscan2
- EPHA7 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 47/77 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65183593, COSV65188030; called by muse, mutect2, varscan2
- EPRS1 | c.2573T>A p.L858Q | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs763318858; called by muse, mutect2, varscan2
- ERC2 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.202); catalogued as rs1316576106; called by muse, mutect2, varscan2
- ERICH3 | c.32C>A p.A11D | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1378686951, COSV58602430; called by muse, mutect2, varscan2
- ESRRB | c.35G>T p.C12F | Missense Mutation (SNP) | VAF 77/148 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs200198676; called by muse, mutect2, varscan2
- EXOSC7 | c.366G>C p.K122N | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99652123; called by muse, mutect2, varscan2
- FAM171A1 | c.1333G>T p.D445Y | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV65316423; called by muse, mutect2, varscan2
- FAM47B | c.710C>A p.P237Q | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV100264049, COSV61454309; called by mutect2, varscan2
- FAM47B | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100264677; called by muse, mutect2, varscan2
- FAM71B | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.074); catalogued as COSV100261863; called by muse, mutect2, varscan2
- FAT3 | c.3170G>T p.R1057L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.999); catalogued as rs778207778, COSV53083845; called by muse, mutect2, varscan2
- FAT3 | c.3983C>A p.T1328K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53143308; called by muse, mutect2, varscan2
- FAT3 | c.4564G>A p.E1522K | Missense Mutation (SNP) | VAF 74/244 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.356); catalogued as rs748097452, COSV53094893, COSV99971876; called by muse, mutect2, varscan2
- FLG | c.3812G>T p.S1271I | Missense Mutation (SNP) | VAF 102/214 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs768867897; called by muse, mutect2, varscan2
- FMN2 | c.2833C>A p.P945T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.3); catalogued as rs769914439; called by muse, mutect2, varscan2
- FMN2 | c.4530G>T p.Q1510H | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60431290; called by muse, mutect2, varscan2
- FMO1 | c.1061A>C p.K354T | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100707681; called by muse, mutect2, varscan2
- FNIP2 | c.1000T>G p.F334V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52442898; called by muse, mutect2, varscan2
- FOXD4L3 | c.1034G>T p.C345F | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as rs782665638; called by muse, mutect2, varscan2
- FUT9 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.82); PolyPhen benign (0.009); catalogued as COSV100133657; called by muse, mutect2, varscan2
- GABRA4 | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.065); catalogued as COSV51937241; called by muse, mutect2, varscan2
- GALNT13 | c.1319A>T p.Q440L | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV67230667; called by muse, mutect2, varscan2
- GALNTL5 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.088); catalogued as COSV101217760; called by muse, varscan2
- GCNA | c.1873C>A p.P625T | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1484456502; called by muse, mutect2, varscan2
- GFOD2 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1206337026; called by muse, mutect2, varscan2
- GIMAP4 | c.358G>T p.V120L | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763091896, COSV55434829; called by muse, mutect2
- GLRB | c.65C>A p.S22Y | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV52414343; called by muse, mutect2, varscan2
- GNG4 | c.83G>T p.C28F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV63999877; called by muse, mutect2, varscan2
- GP6 | c.388G>T p.V130L | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV59977190; called by muse, mutect2, varscan2
- GPD1 | c.22A>G p.I8V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as rs1240651049; called by muse, mutect2, varscan2
- GPR101 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1470717869; called by muse, mutect2, varscan2
- GPR151 | c.316C>A p.L106I | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as rs147138565; called by muse, mutect2, varscan2
- GPR158 | c.2761C>A p.Q921K | Missense Mutation (SNP) | VAF 71/222 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as COSV100894243, COSV66273532; called by muse, mutect2, varscan2
- GPR55 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.763); catalogued as COSV67408839; called by muse, mutect2, varscan2
- GRIA3 | c.2497G>C p.G833R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM074896; called by muse, mutect2, varscan2
- GRIA4 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1320466480; called by muse, mutect2, varscan2
- H3C3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 49/105 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); catalogued as rs778244215; called by muse, mutect2, varscan2
- H4C13 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV60693656, COSV60694804; called by muse, mutect2, varscan2
- HADH | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs972897276; called by muse, mutect2, varscan2
- HCN1 | c.2636C>G p.P879R | Missense Mutation (SNP) | VAF 93/124 reads (75%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.021); catalogued as COSV100298038, COSV57538566; called by muse, mutect2, varscan2
- HDAC9 | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.737); catalogued as COSV67774064; called by muse, varscan2
- HECTD4 | c.8276T>A p.V2759E | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1287628140; called by muse, mutect2, varscan2
- HECW2 | c.4460G>C p.R1487T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV53649803, COSV53662198; called by muse, mutect2, varscan2
- HIPK2 | c.2467C>G p.Q823E | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs373937725, COSV61229475; called by muse, mutect2, varscan2
- HMCN1 | c.5885C>T p.S1962L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.307); catalogued as rs367776519; called by muse, mutect2, varscan2
- HSH2D | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1353680178; called by muse, mutect2, varscan2
- HTR2C | c.969G>A p.M323I | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52221927; called by muse, mutect2, varscan2
- HUWE1 | c.12310C>G p.L4104V | Missense Mutation (SNP) | VAF 50/139 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV53358933; called by muse, mutect2, varscan2
- HVCN1 | c.667C>A p.R223S | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0.088); catalogued as COSV54373915; called by muse, mutect2, varscan2
- HYDIN | c.11082C>A p.F3694L | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1302452687; called by muse, mutect2, varscan2
- IFI44L | c.1358G>T p.*453Lext*5 | Nonstop Mutation (SNP) | VAF 62/276 reads (22%) | catalogued as COSV100654878; called by muse, mutect2, varscan2
- IFNA17 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 173/300 reads (58%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as rs767266392, COSV69738303; called by muse, mutect2, varscan2
- IGHV3-20 | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 66/428 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.393); catalogued as rs1555454637; called by muse, varscan2
- IL36B | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.194); catalogued as rs1351275384; called by muse, mutect2, varscan2
- INHBA | c.636C>A p.D212E | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as rs149369067, COSV99637020; called by muse, mutect2, varscan2
- INTS6L | c.429+1G>T p.X143_splice | Splice Site (SNP) | VAF 6/27 reads (22%) | catalogued as rs1556515094; called by muse, mutect2, varscan2
- ITGA10 | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 72/374 reads (19%) | catalogued as rs1553748032; called by muse, mutect2, varscan2
- ITGAD | c.1015C>T p.Q339* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs769031401; called by muse, mutect2, varscan2
- KANSL1 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV99294388; called by muse, mutect2
- KCNJ2 | c.982C>G p.P328A | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV54662031; called by muse, mutect2, varscan2
- KCNJ3 | c.1124C>A p.A375D | Missense Mutation (SNP) | VAF 85/168 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.079); catalogued as COSV54547650; called by muse, mutect2, varscan2
- KCNK17 | c.883G>C p.D295H | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV64684814, COSV64685068; called by muse, mutect2, varscan2
- KDR | c.2892C>A p.D964E | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.944); catalogued as rs1434745794; called by muse, mutect2, varscan2
- KEL | c.104C>A p.P35H | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as rs751328434; called by muse, mutect2, varscan2
- KIAA1755 | c.2638A>G p.K880E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.192); catalogued as rs181716857; called by muse, mutect2, varscan2
- KIF13B | c.1628A>G p.N543S | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.169); catalogued as rs1157157989; called by muse, mutect2, varscan2
- KIF2B | c.1047C>A p.D349E | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.006); catalogued as rs1282766997; called by muse, mutect2, varscan2
- KIT | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55386801, COSV55412859; called by muse, mutect2, varscan2
- KLB | c.2384G>T p.R795L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); catalogued as COSV99961964; called by muse, mutect2, varscan2
- KMT2D | c.14355G>T p.M4785I | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.344); catalogued as COSV99981474; called by muse, mutect2, varscan2
- KNTC1 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV61081835; called by muse, mutect2, varscan2
- KRT12 | c.620C>A p.A207E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs978113022, COSV52431243, COSV52431493; called by muse, mutect2, varscan2
- KRT5 | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.33); catalogued as COSV52860866; called by mutect2, varscan2
- LAMB4 | c.3068C>A p.S1023Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs758453964; called by muse, mutect2, varscan2
- LAMP5 | c.347C>A p.A116E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1400719278; called by mutect2, varscan2
- LMX1A | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139738225, COSV99672509; called by mutect2, varscan2
- LPA | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV60315199; called by muse, mutect2, varscan2
- LRRC66 | c.1663G>T p.V555F | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.368); catalogued as COSV58634661; called by muse, mutect2, varscan2
- LRWD1 | c.1230G>A p.T410= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as rs140653534; called by muse, mutect2, varscan2
- LUZP2 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 47/185 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1332980729; called by muse, mutect2, varscan2
- MAGEC1 | c.3119C>A p.P1040H | Missense Mutation (SNP) | VAF 84/174 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53579580; called by muse, varscan2
- MAGEC1 | c.3196C>A p.R1066S | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs752999850, COSV53571509, COSV53574727; called by muse, varscan2
- MAGEC3 | c.1084G>T p.G362W | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV68924205; called by muse, mutect2
- MAGEL2 | c.3724C>A p.P1242T | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.675); catalogued as COSV100045718; called by muse, mutect2, varscan2
- MCTP2 | c.1584G>T p.G528= | Splice Region (SNP) | VAF 16/37 reads (43%) | catalogued as rs1394695324; called by muse, mutect2, varscan2
- MECP2 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV100318162; called by muse, mutect2, varscan2
- MEN1 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as CD983456; called by muse, mutect2, varscan2
- METTL22 | c.466G>T p.V156F | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as COSV50838014; called by muse, mutect2, varscan2
- METTL27 | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs370149363, COSV99936387; called by muse, mutect2, varscan2
- MGAT3 | c.170C>T p.T57M | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.134); catalogued as COSV100361673; called by muse, mutect2, varscan2
- MGAT4C | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs200901180; called by muse, mutect2, varscan2
- MIER3 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1207352404; called by muse, mutect2, varscan2
- MIXL1 | c.609T>A p.N203K | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs778386600; called by muse, mutect2, varscan2
- MMP26 | c.194G>A p.G65E | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs372359967; called by muse, mutect2, varscan2
- MOCOS | c.474G>C p.M158I | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.196); catalogued as COSV99733567; called by muse, mutect2, varscan2
- MOCS1 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs778501170, COSV100418326; called by muse, mutect2, varscan2
- MOCS1 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV100418720; called by muse, mutect2, varscan2
- MPPED2 | c.685A>T p.R229* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV63898205; called by muse, mutect2, varscan2
- MRM3 | c.265G>C p.E89Q | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.854); catalogued as COSV100022800, COSV100022827; called by muse, mutect2, varscan2
- MRPL38 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 4/7 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as rs1406739879; called by mutect2, varscan2
- MSH4 | c.1978G>T p.E660* | Nonsense Mutation (SNP) | VAF 13/34 reads (38%) | catalogued as COSV54211908; called by muse, mutect2, varscan2
- MTOR | c.6845A>G p.Q2282R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV63874611; called by muse, mutect2, varscan2
- MUC16 | c.40322C>T p.T13441I | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.983); catalogued as rs996377874; called by muse, mutect2, varscan2
- MYCN | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 4/27 reads (15%) | catalogued as COSV55260751; called by muse, mutect2
- MYO18B | c.3079G>A p.G1027R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as rs1162184840; called by muse, mutect2, varscan2
- MYOZ2 | c.461A>G p.Q154R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1236881000; called by muse, mutect2, varscan2
- NALCN | c.2638G>T p.D880Y | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs1249969931, COSV51954872; called by muse, mutect2, varscan2
- NBEA | c.1279del p.A427Qfs*50 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | catalogued as COSV59771243; called by mutect2, pindel, varscan2
- NCKAP5 | c.4370C>A p.T1457N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.693); catalogued as COSV58446589; called by muse, mutect2, varscan2
- NDST4 | c.337G>T p.G113* | Nonsense Mutation (SNP) | VAF 18/82 reads (22%) | catalogued as COSV52108446, COSV52141229; called by muse, mutect2, varscan2
- NKAIN1 | c.370C>A p.R124S | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.81); PolyPhen benign (0.012); catalogued as COSV99744797; called by muse, mutect2, varscan2
- NLRP4 | c.2816T>C p.V939A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs747092094, COSV56719191; called by muse, varscan2
- NLRP5 | c.2260C>A p.P754T | Missense Mutation (SNP) | VAF 42/133 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.132); catalogued as COSV66762946; called by muse, mutect2, varscan2
- NOX1 | c.1621C>A p.R541S | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as rs370641862; called by muse, mutect2, varscan2
- NOX4 | c.844C>G p.Q282E | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV54464961; called by muse, mutect2, varscan2
- NPAS3 | c.1480G>A p.E494K (on ENST00000356141 / NM_001164749.2; = p.E462K on NM_022123.3) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.32); catalogued as rs1246835722, COSV100640279; called by muse, mutect2, varscan2
- NR0B1 | c.531C>A p.F177L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.026); catalogued as rs1294983285; called by muse, mutect2, varscan2
- NR4A2 | c.352G>T p.G118W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs776226389; called by muse, mutect2, varscan2
- NRXN3 | c.1363G>T p.E455* (on ENST00000335750 / NM_001330195.2; = p.E82* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 53/131 reads (40%) | catalogued as COSV59779828; called by muse, mutect2, varscan2
- NSDHL | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs782634753; called by muse, mutect2, varscan2
- NSUN7 | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.041); catalogued as COSV57276290; called by muse, mutect2, varscan2
- NTRK3 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as rs1347879205; called by muse, mutect2, varscan2
- OAS3 | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.061); catalogued as rs368023053, COSV99965935; called by muse, mutect2, varscan2
- ONECUT2 | c.959C>A p.S320* | Nonsense Mutation (SNP) | VAF 5/7 reads (71%) | catalogued as COSV72203594; called by mutect2, varscan2
- OPN1LW | c.848C>A p.P283H | Missense Mutation (SNP) | VAF 127/618 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100885078, COSV64049436; called by muse, varscan2
- OR10C1 | c.422T>A p.V141E (on ENST00000622521; = p.V139E on NM_013941.3) | Missense Mutation (SNP) | VAF 120/218 reads (55%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as rs1019560082; called by muse, mutect2, varscan2
- OR10Q1 | c.947C>A p.S316Y | Missense Mutation (SNP) | VAF 176/343 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57469898; called by muse, mutect2, varscan2
- OR13C9 | c.370G>T p.V124L | Missense Mutation (SNP) | VAF 68/120 reads (57%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as rs771400841; called by muse, mutect2, varscan2
- OR14I1 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV61199331; called by muse, mutect2, varscan2
- OR14K1 | c.429G>T p.M143I | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99315529; called by muse, mutect2, varscan2
- OR1S2 | c.211C>A p.P71T | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56919137; called by muse, mutect2, varscan2
- OR4C13 | c.781G>T p.A261S | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.023); catalogued as rs1555015905; called by muse, mutect2, varscan2
- OR4C15 | c.261C>A p.Y87* (on ENST00000314644; = p.Y33* on NM_001001920.2) | Nonsense Mutation (SNP) | VAF 47/246 reads (19%) | catalogued as COSV58954863; called by muse, mutect2, varscan2
- OR4C46 | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 48/95 reads (51%) | catalogued as COSV60220066, COSV60220306; called by muse, mutect2
- OR4S2 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 66/239 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs762991139, COSV56747769; called by muse, mutect2, varscan2
- OR51I2 | c.404T>C p.V135A | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV58300437; called by muse, mutect2, varscan2
- OR52A1 | c.560T>C p.I187T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs759012912; called by muse, mutect2, varscan2
- OR52E4 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as rs768054651; called by muse, mutect2, varscan2
- OR52J3 | c.424G>T p.V142L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as rs781104512; called by muse, mutect2, varscan2
- OR52M1 | c.759C>G p.I253M | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); catalogued as rs1303616619, COSV64171404; called by muse, mutect2, varscan2
- OR5K4 | c.645G>T p.L215F | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.25); catalogued as COSV100721407; called by muse, mutect2, varscan2
- OR5M11 | c.493del p.L165* | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | catalogued as COSV73141631; called by pindel, varscan2
- OR6Q1 | c.204G>T p.L68F | Missense Mutation (SNP) | VAF 47/179 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as rs559692274; called by muse, varscan2
- OR8B2 | c.643C>T p.L215F | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.998); catalogued as rs772222306; called by muse, mutect2, varscan2
- OR8B8 | c.31C>A p.Q11K | Missense Mutation (SNP) | VAF 34/55 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV60144791; called by muse, mutect2, varscan2
- OR8I2 | c.369C>A p.Y123* | Nonsense Mutation (SNP) | VAF 25/78 reads (32%) | catalogued as rs778219720; called by muse, mutect2, varscan2
- OTOGL | c.890T>A p.V297E (on ENST00000547103; = p.V288E on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs776891390; called by muse, mutect2, varscan2
- OTOGL | c.2544G>T p.E848D (on ENST00000547103; = p.E839D on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs747436019; called by muse, mutect2, varscan2
- PACS2 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.287); catalogued as rs782157245; called by muse, mutect2, varscan2
- PAGE2B | c.226G>T p.A76S | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV66611070; called by muse, mutect2, varscan2
- PAK1IP1 | c.1175A>T p.Q392L | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs765805578; called by muse, mutect2, varscan2
- PAPPA2 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 83/371 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62779735; called by mutect2, varscan2
- PARP4 | c.4847-1G>T p.X1616_splice | Splice Site (SNP) | VAF 19/59 reads (32%) | catalogued as rs1309023111, COSV101132000; called by muse, mutect2, varscan2
- PCDH11X | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 31/96 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100012288; called by muse, varscan2
- PCDH17 | c.770C>G p.P257R | Missense Mutation (SNP) | VAF 19/32 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64973664, COSV64976436; called by muse, mutect2, varscan2
- PCDH9 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.509); catalogued as rs1403883434, COSV60529235; called by muse, mutect2, varscan2
- PCDHA3 | c.1526C>A p.S509* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV100793300; called by muse, mutect2, varscan2
- PCDHB2 | c.1597G>T p.V533L | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.917); catalogued as rs571621697; called by muse, mutect2, varscan2
- PCDHB3 | c.1744C>G p.P582A | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.011); catalogued as COSV50604835, COSV99166624; called by muse, mutect2, varscan2
- PCDHB4 | c.2108C>G p.S703W | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.188); catalogued as COSV52025300; called by muse, mutect2, varscan2
- PCMTD1 | c.395G>T p.S132I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100859610; called by muse, mutect2
- PCOLCE2 | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 67/109 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs762505464; called by muse, varscan2
- PDCD4 | c.1259C>T p.P420L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99700743; called by muse, mutect2, varscan2
- PDE1A | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs747745891, COSV59515003; called by muse, mutect2, varscan2
- PDHA2 | c.958G>T p.D320Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54776936, COSV54781887; called by muse, mutect2, varscan2
- PDILT | c.836T>C p.L279P | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1165583372; called by muse, mutect2, varscan2
- PDK1 | c.975G>T p.L325F | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.067); catalogued as COSV56375297; called by muse, mutect2, varscan2
- PDZK1 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as rs781954403; called by muse, mutect2, varscan2
- PEAR1 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.923); catalogued as rs1489992655; called by muse, mutect2, varscan2
- PHKA2 | c.3496C>A p.Q1166K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101176657; called by muse, mutect2, varscan2
- PIGZ | c.920C>A p.A307E | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.893); catalogued as rs368275616; called by mutect2, varscan2
- PIK3AP1 | c.1863C>A p.N621K | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs775513848; called by muse, mutect2, varscan2
- PKHD1L1 | c.848G>A p.R283Q | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs199719733; called by muse, mutect2, varscan2
- PLOD3 | c.393G>T p.Q131H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs1351137791; called by muse, mutect2, varscan2
- PLXNA1 | c.655G>T p.V219L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.983); catalogued as COSV99304374; called by muse, mutect2, varscan2
- PLXNB3 | c.5262-1G>T p.X1754_splice | Splice Site (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100737832; called by muse, mutect2, varscan2
- PNLIPRP1 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs959649900, COSV62611937; called by muse, mutect2, varscan2
- PNLIPRP3 | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65049997; called by muse, mutect2, varscan2
- POM121L12 | c.725C>A p.P242H | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.605); catalogued as COSV68692550; called by muse, mutect2, varscan2
- POTEF | c.115G>A p.G39S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); catalogued as rs371345451; called by muse, mutect2, varscan2
- POU4F1 | c.970G>T p.A324S | Missense Mutation (SNP) | VAF 9/10 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV65884331; called by muse, mutect2, varscan2
- PPM1L | c.907G>T p.G303C | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99862123; called by muse, mutect2, varscan2
- PPP1R32 | c.303T>G p.H101Q | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs895319863; called by muse, mutect2, varscan2
- PPP1R3A | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 7/154 reads (5%) | catalogued as COSV99492399; called by muse, mutect2
- PRDM16 | c.3607G>A p.E1203K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as COSV54588619; called by muse, mutect2, varscan2
- PRG2 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100314916; called by muse, mutect2, varscan2
- PRH1 | c.29T>C p.L10P | Missense Mutation (SNP) | VAF 15/121 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs757473997; called by muse, mutect2
- PRSS53 | c.897G>C p.L299F | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as rs1385676678; called by muse, mutect2
- PSMD11 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 26/79 reads (33%) | catalogued as COSV55578625; called by muse, mutect2, varscan2
- PTEN | c.1002C>G p.N334K | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1554825620; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTPRD | c.3602C>A p.T1201N | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV61990305; called by muse, mutect2, varscan2
- PTPRD | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61927103; called by muse, mutect2, varscan2
- PTPRZ1 | c.4963C>G p.L1655V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1180458410, COSV66430042; called by muse, mutect2, varscan2
- RASGRF2 | c.1166C>G p.P389R | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54122089; called by muse, mutect2, varscan2
- RBM47 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1167415315; called by muse, mutect2, varscan2
- RBPJL | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146643791; called by muse, mutect2, varscan2
- RELN | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as COSV58992075; called by muse, mutect2, varscan2
- RFTN2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as rs1226130777; called by mutect2, varscan2
- RHBDL3 | c.839G>C p.G280A | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99283582; called by muse, mutect2, varscan2
- RIBC1 | c.548C>A p.A183E | Missense Mutation (SNP) | VAF 13/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV51447432; called by muse, mutect2
- RNASEL | c.340A>G p.K114E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs1413138738; called by muse, varscan2
- RNGTT | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.115); catalogued as COSV55647670; called by muse, mutect2, varscan2
- ROBO2 | c.695T>G p.I232S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.439); catalogued as COSV59934144; called by muse, mutect2, varscan2
- RP1L1 | c.4404G>T p.Q1468H | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs778304586; called by muse, mutect2, varscan2
- RPS6KA6 | c.1333C>T p.H445Y | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99424863; called by mutect2, varscan2
- RTL3 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV100330025; called by muse, mutect2, varscan2
- RTP5 | c.907G>T p.A303S | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.44); PolyPhen benign (0.332); catalogued as rs1250517967; called by muse, mutect2, varscan2
- RUNDC3B | c.669G>T p.K223N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.213); catalogued as rs1413183757; called by muse, mutect2, varscan2
- RUNX1T1 | c.734C>A p.P245Q (on ENST00000265814 / NM_001198628.1; = p.P218Q on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56158446; called by muse, mutect2, varscan2
- RYR1 | c.8242C>A p.P2748T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV62110368; called by muse, varscan2
- RYR2 | c.14720C>A p.T4907N | Missense Mutation (SNP) | VAF 68/384 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63663048; called by muse, varscan2
- RYR3 | c.7979C>G p.T2660R (on ENST00000389232; = p.T2661R on NM_001036.6) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.456); catalogued as rs200246566; called by muse, mutect2, varscan2
- SAXO1 | c.1360A>T p.S454C | Missense Mutation (SNP) | VAF 59/105 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs1265430004; called by muse, mutect2, varscan2
- SCN2A | c.1881G>T p.Q627H | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.974); catalogued as rs1466478648; called by muse, mutect2, varscan2
- SDR16C5 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100374100; called by muse, mutect2, varscan2
- SEMA3D | c.2240del p.G747Afs*10 | Frame Shift Del (DEL) | VAF 26/74 reads (35%) | catalogued as rs770739903, COSV52394959; called by mutect2, pindel, varscan2
- SENP7 | c.2991G>T p.L997F | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239418168; called by muse, mutect2, varscan2
- SERPINA5 | c.707T>A p.M236K | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759289438; called by muse, mutect2, varscan2
- SHROOM2 | c.2489G>T p.R830L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.67); PolyPhen benign (0.011); catalogued as COSV101098266; called by muse, mutect2, varscan2
- SKOR1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100408434; called by muse, mutect2, varscan2
- SLA2 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as rs1472927741; called by muse, mutect2, varscan2
- SLC18A3 | c.1077C>A p.Y359* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV60320553; called by mutect2, varscan2
- SLC23A2 | c.1370G>T p.R457L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.986); catalogued as COSV57772281; called by muse, mutect2, varscan2
- SLC25A39 | c.695T>C p.L232P (on ENST00000377095 / NM_001143780.3; = p.L224P on NM_016016.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs372262650; called by muse, mutect2, varscan2
- SLC25A47 | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs755073618; called by muse, mutect2
- SLC35D1 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 28/63 reads (44%) | catalogued as COSV52432374; called by muse, mutect2, varscan2
- SLC36A3 | c.62C>A p.S21* | Nonsense Mutation (SNP) | VAF 34/50 reads (68%) | catalogued as rs770281138; called by muse, mutect2, varscan2
- SLC38A4 | c.1298C>A p.P433Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749089697; called by muse, mutect2, varscan2
- SLC4A10 | c.461G>A p.W154* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | catalogued as rs1253123554; called by muse, mutect2, varscan2
- SLITRK4 | c.174G>T p.W58C | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); catalogued as rs1556428278; called by muse, mutect2, varscan2
- SMARCC2 | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.651); catalogued as COSV99911687; called by muse, varscan2
- SMARCD1 | c.299G>T p.R100L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.247); catalogued as COSV57317637; called by muse, mutect2
- SORCS1 | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53842856, COSV99549674; called by muse, varscan2
- SOS1 | c.3320C>A p.S1107Y | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV101217327; called by muse, mutect2, varscan2
- SPAG16 | c.757G>T p.G253W | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as rs1226562285, COSV55988189; called by muse, mutect2, varscan2
- SPANXN1 | c.130A>C p.K44Q | Missense Mutation (SNP) | VAF 95/428 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.713); catalogued as COSV100979394; called by muse, mutect2, varscan2
- SPATC1 | c.1661T>A p.L554Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161521831; called by muse, mutect2, varscan2
- SPEF2 | c.5056G>A p.E1686K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs766250986; called by muse, mutect2, varscan2
- SPINK2 | c.99G>C p.T33= | Splice Region (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99954271; called by mutect2, varscan2
- SPSB1 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.354); catalogued as rs971896678; called by muse, mutect2, varscan2
- STXBP6 | c.452-1G>T p.X151_splice | Splice Site (SNP) | VAF 30/170 reads (18%) | catalogued as rs1275048819; called by muse, mutect2, varscan2
- STYXL2 | c.815G>T p.R272L | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99609932; called by muse, mutect2, varscan2
- STYXL2 | c.2764G>T p.A922S | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.036); catalogued as COSV54803455; called by muse, mutect2, varscan2
- SUV39H2 | c.221C>T p.S74F (on ENST00000354919 / NM_001193424.2; = p.S14F on NM_024670.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs1460893772; called by muse, mutect2, varscan2
- SYNGR1 | c.566G>T p.S189I | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs950602735; called by muse, mutect2, varscan2
- SYT10 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs143923961; called by muse, mutect2, varscan2
- SYT13 | c.766G>A p.G256R | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547784718, COSV50076536; called by muse, mutect2, varscan2
- SYT4 | c.535G>T p.G179C | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV54902913; called by muse, mutect2, varscan2
- SZT2 | c.8436G>A p.M2812I (on ENST00000634258 / NM_001365999.1; = p.M2755I on NM_015284.4) | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.663); catalogued as rs772705966, COSV100987588; called by muse, mutect2, varscan2
- TBC1D1 | c.2558G>T p.G853V | Missense Mutation (SNP) | VAF 53/159 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54720645; called by muse, mutect2, varscan2
- TBCD | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 12/15 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs768633151; called by muse, mutect2, varscan2
- TBX3 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1006993913; called by muse, mutect2, varscan2
- TEDDM1 | c.610T>A p.W204R | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62380818; called by muse, mutect2, varscan2
- TENM3 | c.2438G>T p.R813L | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV69316690; called by muse, mutect2, varscan2
- TEX26 | c.182C>A p.S61* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV100993982; called by muse, mutect2, varscan2
- THSD7A | c.2788C>G p.R930G | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70275543; called by muse, mutect2, varscan2
- TIFAB | c.129C>A p.D43E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.087); catalogued as COSV72345680; called by muse, mutect2, varscan2
- TIGD7 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 19/65 reads (29%) | catalogued as COSV51916875; called by muse, mutect2, varscan2
- TIMD4 | c.868C>A p.Q290K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.83); PolyPhen benign (0.092); catalogued as rs1190493443, COSV99192513; called by muse, mutect2, varscan2
- TM7SF3 | c.648G>C p.Q216H | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV58001429; called by muse, mutect2
- TNS1 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235601145; called by muse, mutect2, varscan2
- TP63 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM013068, COSV53202707; called by muse, mutect2, varscan2
- TPTE | c.666G>T p.R222= (on ENST00000618007 / NM_199261.4; = p.R204= on NM_199259.4) | Splice Region (SNP) | VAF 4/38 reads (11%) | catalogued as rs1273898804; called by muse, mutect2, varscan2
- TRAV27 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs1277084719; called by muse, mutect2, varscan2
- TRIM29 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1386859398; called by muse, mutect2, varscan2
- TSPYL1 | c.733C>G p.Q245E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as COSV63994235; called by muse, mutect2, varscan2
- TTN | c.57451G>T p.G19151W (on ENST00000591111; = p.G11727W on NM_003319.4) | Missense Mutation (SNP) | VAF 32/72 reads (44%) | PolyPhen probably damaging (0.963); catalogued as COSV60432233; called by muse, mutect2, varscan2
- TTN | c.54604G>A p.E18202K (on ENST00000591111; = p.E10778K on NM_003319.4) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | PolyPhen possibly damaging (0.829); catalogued as rs1185186867, COSV99045393; called by muse, mutect2, varscan2
- TTN | c.49348G>A p.D16450N (on ENST00000591111; = p.D9026N on NM_003319.4) | Missense Mutation (SNP) | VAF 13/69 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV60077918; called by muse, mutect2, varscan2
- TUSC3 | c.922G>T p.V308F | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.134); catalogued as rs1419699214; called by muse, mutect2, varscan2
- UBQLN3 | c.1361G>T p.R454M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV61165004; called by mutect2, varscan2
- UNC79 | c.1490A>T p.Q497L (on ENST00000393151 / NM_001346218.2; = p.Q320L on NM_020818.5) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56407524; called by muse, mutect2, varscan2
- UPF3A | c.350A>G p.N117S | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV60895460; called by muse, mutect2, varscan2
- USF3 | c.6034C>T p.P2012S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.999); catalogued as rs1481252720; called by muse, mutect2, varscan2
- USH2A | c.5581G>T p.G1861C | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM135008; called by muse, mutect2, varscan2
- USP24 | c.4250G>T p.C1417F | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1391705144; called by muse, mutect2, varscan2
- USP9X | c.4442G>T p.G1481V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.704); catalogued as COSV61066222; called by muse, mutect2, varscan2
- UTP6 | c.1672C>T p.H558Y | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1270588091; called by muse, mutect2, varscan2
- VPS52 | c.635A>G p.Q212R | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as rs1179497215; called by muse, mutect2, varscan2
- XIRP2 | c.403G>T p.G135W (on ENST00000628543; = p.G310W on NM_152381.6) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.283); catalogued as rs372108576; called by muse, mutect2, varscan2
- XPO6 | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV58970518; called by muse, mutect2, varscan2
- YY1AP1 | c.1871A>G p.N624S (on ENST00000295566 / NM_139118.2; = p.N567S on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as rs376401461; called by muse, mutect2, varscan2
- ZAN | c.733G>A p.V245M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); catalogued as rs747747456; called by mutect2, varscan2
- ZBTB34 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59859534; called by muse, mutect2, varscan2
- ZFHX4 | c.7533C>A p.H2511Q | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51437699; called by muse, mutect2, varscan2
- ZNF33A | c.818A>T p.H273L (on ENST00000458705 / NM_006974.3; = p.H274L on NM_006954.2) | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.216); catalogued as COSV56725072; called by muse, mutect2, varscan2
- ZNF536 | c.1301T>A p.L434Q | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1298121928, COSV62834146; called by muse, mutect2, varscan2
- ZNF681 | c.808A>G p.T270A | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.123); catalogued as rs750151055, COSV68075607; called by muse, mutect2, varscan2
- ZNF711 | c.1076G>C p.R359T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.619); catalogued as COSV52151132; called by muse, mutect2, varscan2
- ZP4 | c.1604C>A p.P535Q | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.068); catalogued as rs746959143; called by mutect2, varscan2
- A2M | c.375G>T p.E125D | Missense Mutation (SNP) | VAF 41/66 reads (62%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- AAK1 | c.339C>G p.N113K | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT tolerated (0.19); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ABCA1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ABCA1 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ABCA10 | c.1154T>C p.F385S | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- ABCA12 | c.5332C>G p.Q1778E (on ENST00000272895 / NM_173076.3; = p.Q1460E on NM_015657.3) | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.94); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCD2 | c.1505A>T p.E502V | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ABTB1 | c.91G>T p.V31L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- AC004922.1 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); called by muse, mutect2
- AC004922.1 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); called by muse, mutect2
- ACTC1 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACTRT1 | c.885T>A p.Y295* | Nonsense Mutation (SNP) | VAF 84/222 reads (38%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.1836C>A p.D612E | Missense Mutation (SNP) | VAF 16/157 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ADAMTS9 | c.3355-1G>T p.X1119_splice | Splice Site (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.2768A>T p.Q923L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- ADCY2 | c.1906T>C p.F636L | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.033); called by muse, mutect2
- ADGRB3 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ADGRG4 | c.2311G>T p.A771S | Missense Mutation (SNP) | VAF 85/242 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADGRG4 | c.5987C>A p.T1996N | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ADGRG4 | c.8321A>T p.D2774V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIFM1 | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 147/471 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- AJAP1 | c.182C>A p.P61H | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.774); called by muse, mutect2, varscan2
- AK7 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- AK7 | c.1666G>T p.A556S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.9); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- AKAP4 | c.1113G>T p.L371F | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AKR1B1 | c.142G>A p.V48M | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- AKR1B10 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AMER2 | c.1142G>T p.C381F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- ANK2 | c.11410C>A p.P3804T | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); called by muse, varscan2
- ANO5 | c.101G>C p.S34T | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AOC3 | c.1799C>G p.P600R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AOX1 | c.2536G>A p.G846R | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AOX1 | c.2537G>T p.G846V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- APOB | c.5145G>T p.Q1715H | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- APOB | c.3075G>C p.E1025D | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- APOBR | c.2371G>T p.A791S (on ENST00000431282; = p.A800S on NM_018690.4) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- ARFGAP1 | c.560G>T p.G187V | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ARFGEF1 | c.1241A>T p.K414M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- ARHGAP9 | c.491C>A p.S164Y | Missense Mutation (SNP) | VAF 13/147 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2
- ARMC3 | c.934T>A p.F312I | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- ARV1 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ASAP1 | c.1621G>T p.E541* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ASB12 | c.332T>C p.F111S | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASH1L | c.1122G>C p.K374N | Missense Mutation (SNP) | VAF 44/309 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ASIC1 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ASTN1 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATF6B | c.1787C>G p.S596C | Missense Mutation (SNP) | VAF 27/168 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP10A | c.2266C>A p.P756T | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ATP10A | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 43/58 reads (74%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- ATP1B4 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP5MC3 | c.121-1G>A p.X41_splice | Splice Site (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2, varscan2
- ATP7A | c.3692C>A p.T1231K | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ATP8A2 | c.535G>C p.V179L | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, varscan2
- ATR | c.7912C>T p.L2638F | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- AWAT1 | c.919C>A p.H307N | Missense Mutation (SNP) | VAF 79/191 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- BCORL1 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- BEND2 | c.1835G>T p.G612V | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- BOC | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | called by muse, mutect2, varscan2
- BPIFA3 | c.606C>A p.H202Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- BTBD11 | c.3045G>T p.E1015D (on ENST00000280758 / NM_001018072.2; = p.E552D on NM_001017523.2) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- BTBD11 | c.3193C>T p.Q1065* (on ENST00000280758 / NM_001018072.2; = p.Q602* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 31/49 reads (63%) | called by muse, mutect2, varscan2
- C10orf71 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 102/150 reads (68%) | SIFT tolerated (0.54); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- C8orf74 | c.347A>G p.H116R | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- CA14 | c.644C>A p.S215* | Nonsense Mutation (SNP) | VAF 29/148 reads (20%) | called by muse, mutect2, varscan2
- CACNA1C | c.3812T>C p.I1271T | Missense Mutation (SNP) | VAF 121/198 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CADM2 | c.554G>T p.S185I (on ENST00000407528 / NM_001167674.2; = p.S187I on NM_153184.4) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- CAMK2D | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 37/163 reads (23%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- CAMTA1 | c.3194G>C p.G1065A | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CAPN5 | c.1370G>T p.G457V (on ENST00000456580; = p.G417V on NM_004055.5) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CASK | c.1156C>A p.L386M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CATSPERD | c.1661G>C p.G554A | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CBFB | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCDC136 | c.1379T>A p.L460H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC149 | c.706C>A p.L236I | Missense Mutation (SNP) | VAF 83/221 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC172 | c.329A>C p.K110T | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CCKBR | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CCL3L3 | c.256G>T p.V86F | Missense Mutation (SNP) | VAF 61/94 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- CCNB3 | c.3902C>A p.S1301Y | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT6A | c.925G>T p.G309C | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCZ1B | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.219); called by mutect2, varscan2
- CD4 | c.215-2A>C p.X72_splice | Splice Site (SNP) | VAF 64/331 reads (19%) | called by muse, varscan2
- CD40LG | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- CDCA7L | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CDH12 | c.1271G>C p.W424S | Missense Mutation (SNP) | VAF 89/140 reads (64%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- CDX4 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.67); called by muse, mutect2
- CEBPZ | c.557T>C p.L186P | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- CENPF | c.7868G>A p.R2623K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CFAP47 | c.2213G>T p.S738I | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.674); called by muse, mutect2
- CFAP70 | c.1522C>T p.Q508* | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- CFHR3 | c.400T>A p.W134R | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CGB8 | c.496T>A p.*166Kext*? | Nonstop Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
- CGRRF1 | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- CHL1 | c.2672C>A p.T891K (on ENST00000397491 / NM_001253387.1; = p.T907K on NM_006614.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- CHRM2 | c.677C>G p.A226G | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHRM3 | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 73/137 reads (53%) | called by muse, mutect2, varscan2
- CHRNA1 | c.310C>A p.Q104K (on ENST00000261007 / NM_001039523.3; = p.Q79K on NM_000079.4) | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLIP2 | c.678G>T p.L226= | Splice Region (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2
- CLMN | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLSTN2 | c.413_414insC p.W138Cfs*39 | Frame Shift Ins (INS) | VAF 40/165 reads (24%) | called by mutect2, pindel*, varscan2
- CNGB3 | c.259G>C p.D87H | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- CNTN4 | c.1152T>A p.C384* | Nonsense Mutation (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.140C>A p.A47D | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- COL11A2 | c.5191C>A p.P1731T (on ENST00000341947 / NM_080680.3; = p.P1624T on NM_080679.2) | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.334); called by muse, mutect2, varscan2
- COL12A1 | c.4131C>A p.N1377K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.739); called by muse, mutect2
- COL1A2 | c.3293C>T p.P1098L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- COL25A1 | c.1296C>A p.N432K | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- COL4A2 | c.662C>A p.P221H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL4A3 | c.801G>T p.M267I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL4A6 | c.2365G>C p.G789R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A5 | c.6958T>A p.Y2320N (on ENST00000312481; = p.Y2316N on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- COL6A6 | c.4618G>T p.G1540C | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPB2 | c.254A>C p.N85T | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- CPSF2 | c.1443A>T p.K481N | Missense Mutation (SNP) | VAF 69/151 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPT1A | c.1070G>T p.R357L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CPT1B | c.1397A>G p.Q466R | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- CREB5 | c.319G>T p.G107W (on ENST00000357727 / NM_182898.4; = p.G100W on NM_004904.3) | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); called by muse, varscan2
- CRP | c.75G>T p.K25N | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- CRTAM | c.854A>T p.K285I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CSMD3 | c.10753C>T p.P3585S (on ENST00000297405 / NM_001363185.1; = p.P3416S on NM_052900.3) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CSMD3 | c.2436G>T p.Q812H (on ENST00000297405 / NM_001363185.1; = p.Q708H on NM_052900.3) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CSMD3 | c.1765A>G p.I589V (on ENST00000297405 / NM_001363185.1; = p.I485V on NM_052900.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); called by muse, varscan2
- CSNK1G3 | c.683G>C p.R228T | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CTNNBL1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- CUL7 | c.277C>G p.Q93E | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CWC22 | c.1225G>T p.G409* | Nonsense Mutation (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- CWH43 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- CXorf66 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- CYP19A1 | c.723del p.Y241* | Frame Shift Del (DEL) | VAF 25/48 reads (52%) | called by mutect2, pindel, varscan2
- DAAM2 | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); called by muse, mutect2
- DAB2 | c.1946A>T p.K649M | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAB2 | c.232G>A p.G78R | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCAF8L1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DCAF8L1 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- DCAF8L1 | c.906C>A p.F302L | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- DCDC1 | c.2854G>T p.V952F (on ENST00000597505 / NM_001367979.1; = p.V59F on NM_020869.3) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCTD | c.201G>C p.W67C | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCUN1D3 | c.856dup p.E286Gfs*11 | Frame Shift Ins (INS) | VAF 17/44 reads (39%) | called by mutect2, pindel, varscan2
- DDX54 | c.2254A>T p.K752* | Nonsense Mutation (SNP) | VAF 35/59 reads (59%) | called by muse, mutect2, varscan2
- DEFB116 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 127/415 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.665); called by muse, mutect2, varscan2
- DGKI | c.1966G>A p.G656S | Missense Mutation (SNP) | VAF 84/248 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- DNAH3 | c.6499G>T p.G2167C | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAJB4 | c.382G>T p.D128Y | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- DNAJC6 | c.2453A>T p.E818V | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- DNHD1 | c.11229G>T p.K3743N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK10 | c.4977G>C p.K1659N | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); called by muse, mutect2, varscan2
- DRICH1 | c.254A>G p.E85G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- DRP2 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, varscan2
- DSC3 | c.1372G>T p.V458F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- DSP | c.5435G>C p.R1812T | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.436); called by muse, mutect2
- DST | c.20346G>C p.W6782C (on ENST00000361203 / NM_001374722.1; = p.W4479C on NM_015548.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DYSF | c.2008C>A p.H670N | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- ELF1 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- EML1 | c.883T>C p.S295P | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ENAM | c.2741G>A p.S914N | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ENPP3 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPDR1 | c.623G>C p.S208T | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- EPG5 | c.183G>T p.K61N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EPHB1 | c.2003A>C p.E668A | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB6 | c.788G>T p.C263F | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- ERBB4 | c.1674G>T p.Q558H | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- ERC1 | c.133A>G p.S45G | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC4 | c.2591G>T p.R864L | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ERCC6L | c.1713C>A p.Y571* | Nonsense Mutation (SNP) | VAF 13/127 reads (10%) | called by muse, mutect2, varscan2
- ESRRB | c.34T>C p.C12R | Missense Mutation (SNP) | VAF 78/149 reads (52%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- F2RL2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); called by muse, mutect2
- F8 | c.4089G>A p.M1363I | Missense Mutation (SNP) | VAF 66/408 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAIM | c.54G>C p.K18N | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- FAM104B | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.024); called by mutect2, varscan2
- FAM120A | c.2882G>T p.R961M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- FAM135B | c.3745C>T p.P1249S | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FAM180A | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.429); called by muse, mutect2, varscan2
- FAM3D | c.674A>C p.*225Sext*100 | Nonstop Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- FAM47C | c.557T>A p.F186Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- FANCF | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
- FAT4 | c.4297A>G p.I1433V | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBXW10 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by mutect2, varscan2
- FCER1A | c.408G>T p.R136S | Missense Mutation (SNP) | VAF 14/112 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.394); called by muse, mutect2
- FCRL5 | c.1847G>T p.G616V | Missense Mutation (SNP) | VAF 192/396 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- FEZF1 | c.200T>A p.L67H | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FGA | c.2282C>A p.T761N | Missense Mutation (SNP) | VAF 66/122 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- FGD4 | c.1114G>A p.D372N | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGF12 | c.406T>C p.Y136H (on ENST00000454309 / NM_021032.5; = p.Y74H on NM_004113.6) | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- FHL1 | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- FLG2 | c.4272T>A p.H1424Q | Missense Mutation (SNP) | VAF 280/413 reads (68%) | SIFT tolerated (0.59); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- FLT3 | c.701G>T p.R234I | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- FMN2 | c.5089C>A p.Q1697K | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FNDC4 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1241A>T p.K414M | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- FRMPD2 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- FSCB | c.1226C>A p.P409Q | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- FSTL5 | c.121C>T p.H41Y | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- FXN | c.28G>T p.G10C (on ENST00000377270; = p.G85C on NM_000144.5) | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- GABRP | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 80/214 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, varscan2
- GAK | c.569G>T p.C190F | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GALC | c.968G>C p.G323A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- GAS2L3 | c.1802G>C p.G601A | Missense Mutation (SNP) | VAF 32/52 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GBA3 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 70/174 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- GDF10 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.182); called by muse, mutect2
- GDF6 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLA | c.1003G>A p.D335N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GLI1 | c.2587G>C p.G863R | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- GLIPR2 | c.73G>C p.G25R | Missense Mutation (SNP) | VAF 124/215 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- GLRA2 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- GLRA2 | c.458G>T p.R153L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- GPR101 | c.945C>A p.D315E | Missense Mutation (SNP) | VAF 121/307 reads (39%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR155 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- GPR37 | c.1834C>G p.H612D | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- GPR85 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- GRIA2 | c.2608A>T p.K870* | Nonsense Mutation (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- GRID2 | c.152T>A p.L51H | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GRM8 | c.1094A>T p.E365V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- GUCA1C | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- HACE1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, varscan2
- HERC2 | c.6776A>T p.Q2259L | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HERC3 | c.778-1G>C p.X260_splice | Splice Site (SNP) | VAF 58/198 reads (29%) | called by muse, varscan2
- HGF | c.1330G>T p.D444Y | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HMCN1 | c.11770C>A p.P3924T | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HNF1B | c.79G>T p.V27F | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HOOK1 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HOXC4 | c.692C>G p.A231G | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HPCA | c.68C>G p.S23* | Nonsense Mutation (SNP) | VAF 24/89 reads (27%) | called by muse, mutect2, varscan2
- HRNR | c.2684A>T p.Q895L | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- HSPA4L | c.2284C>T p.Q762* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | called by muse, mutect2, varscan2
- HTR1E | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 72/126 reads (57%) | SIFT tolerated (0.53); PolyPhen benign (0.011); called by mutect2, varscan2
- IGF2BP2 | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IGFBP5 | c.682A>C p.K228Q | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGHMBP2 | c.2125C>G p.Q709E | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, varscan2
- IGKV3-7 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- IGLV5-37 | c.196A>T p.R66W | Missense Mutation (SNP) | VAF 38/54 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- IGLV6-57 | c.63T>A p.F21L | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGSF22 | c.2245C>A p.P749T (on ENST00000319338; = p.P850T on NM_173588.4) | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IKZF2 | c.1377G>C p.K459N | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- IL1RAPL2 | c.563G>C p.W188S | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL1RL1 | c.557A>T p.N186I | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- IST1 | c.194C>G p.A65G (on ENST00000535424 / NM_001270976.1; = p.A52G on NM_014761.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGAX | c.1376G>T p.G459V | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ITGB1BP2 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ITPKB | c.1474C>G p.Q492E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2
- ITPKB | c.1174A>T p.R392W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ITPR1 | c.7823A>T p.K2608M (on ENST00000354582; = p.K2553M on NM_002222.7) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- JAKMIP1 | c.690dup p.G231Wfs*15 | Frame Shift Ins (INS) | VAF 80/208 reads (38%) | called by mutect2, varscan2
- KCNA5 | c.1416G>T p.W472C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNB2 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 88/168 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- KCNH7 | c.1578G>C p.L526F | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- KCTD20 | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- KCTD3 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA0586 | c.3757T>C p.Y1253H (on ENST00000619416 / NM_001244190.2; = p.Y1192H on NM_014749.5) | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.742); called by muse, mutect2
- KIAA1549L | c.5146C>A p.P1716T (on ENST00000321505; = p.P2013T on NM_012194.3) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIF13A | c.4204G>A p.D1402N | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.101); called by muse, mutect2
- KIF24 | c.3739A>T p.N1247Y | Missense Mutation (SNP) | VAF 41/55 reads (75%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF27 | c.1177A>T p.R393W | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- KIF5A | c.2540T>C p.L847P | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF6 | c.1525C>A p.P509T | Missense Mutation (SNP) | VAF 44/209 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIT | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- KLHL34 | c.1631A>G p.Y544C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KMO | c.589T>A p.L197M | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- KMT2C | c.2653G>T p.G885C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT4 | c.695A>T p.N232I | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); called by muse, mutect2
- KRT71 | c.641A>G p.E214G | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT8 | c.977G>T p.G326V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- KRT9 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- KRTAP12-2 | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 66/93 reads (71%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRTAP27-1 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 67/99 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- LAMA1 | c.3221G>T p.C1074F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LAMP5 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LCT | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- LDLRAD4 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LEP | c.297C>A p.N99K | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LIN28B | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LINGO2 | c.1240G>T p.E414* | Nonsense Mutation (SNP) | VAF 35/107 reads (33%) | called by muse, mutect2, varscan2
- LMX1A | c.556G>C p.A186P | Missense Mutation (SNP) | VAF 44/276 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, varscan2
- LNP1 | c.90G>C p.Q30H | Missense Mutation (SNP) | VAF 18/185 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2
- LOXL2 | c.717G>C p.E239D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- LPO | c.1518T>A p.D506E | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRP5 | c.2577C>G p.Y859* | Nonsense Mutation (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- LRRC4C | c.1435dup p.T479Nfs*33 | Frame Shift Ins (INS) | VAF 10/36 reads (28%) | called by mutect2, pindel
- LRRC7 | c.2826T>A p.S942R (on ENST00000651989 / NM_001370785.2; = p.S909R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- LRRK2 | c.91_94del p.Q31* | Frame Shift Del (DEL) | VAF 14/24 reads (58%) | called by mutect2, pindel, varscan2
- LRTM1 | c.687C>A p.Y229* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- LSM11 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LSM8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.266); called by muse, mutect2
- MAP1B | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- MAP1B | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- MAP4 | c.2526A>T p.K842N | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- MAP4K1 | c.299A>T p.Q100L | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAPK10 | c.862A>T p.K288* (on ENST00000359221 / NM_001351625.2; = p.K326* on NM_002753.5) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- MARCHF10 | c.1010A>G p.E337G | Missense Mutation (SNP) | VAF 29/253 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCHF10 | c.125C>A p.P42Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.564); called by muse, mutect2
- MCF2L2 | c.1863G>T p.R621S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MCM6 | c.498G>C p.R166S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MCOLN3 | c.272A>T p.K91M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MDGA2 | c.2054A>G p.E685G (on ENST00000399232 / NM_001113498.2; = p.E387G on NM_182830.4) | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.27); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- MED12L | c.3937C>A p.R1313S | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.103); called by muse, mutect2
- MED12L | c.4456C>G p.L1486V | Missense Mutation (SNP) | VAF 85/126 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MORF4L1 | c.1075C>G p.R359G (on ENST00000331268 / NM_206839.2; = p.R320G on NM_006791.4) | Missense Mutation (SNP) | VAF 25/40 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MPIG6B | c.586G>C p.E196Q (on ENST00000649779 / NM_138272.3; = p.R202T on NM_025260.4) | Missense Mutation (SNP) | VAF 35/358 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); called by muse, mutect2
- MRC1 | c.2314del p.N773Tfs*79 | Frame Shift Del (DEL) | VAF 46/123 reads (37%) | called by mutect2, varscan2
- MROH2B | c.2515C>A p.L839I | Missense Mutation (SNP) | VAF 68/125 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MROH2B | c.1004C>G p.T335S | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, varscan2
- MSH4 | c.1979A>T p.E660V | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MSL3 | c.1456C>G p.L486V (on ENST00000312196 / NM_078629.4; = p.L320V on NM_006800.4) | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MTMR1 | c.648C>G p.F216L | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.421); called by muse, varscan2
- MTMR1 | c.651C>A p.S217R | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT tolerated (0.48); PolyPhen benign (0.042); called by muse, varscan2
- MTOR | c.3653A>T p.K1218M | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MTUS2 | c.2650A>T p.T884S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.85); PolyPhen benign (0.011); called by muse, mutect2
- MUC16 | c.41212G>A p.G13738S | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MUC16 | c.36889G>A p.G12297R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.162); called by muse, varscan2
- MUSK | c.1974G>T p.M658I | Missense Mutation (SNP) | VAF 98/169 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- MYCBP2 | c.4772C>T p.S1591L (on ENST00000357337; = p.S1629L on NM_015057.5) | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MYH1 | c.2996A>G p.E999G | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- MYO18B | c.2613C>A p.F871L | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO18B | c.3080G>T p.G1027V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- MYO1A | c.1047C>G p.I349M | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NAV3 | c.6019G>T p.V2007F (on ENST00000397909 / NM_001024383.2; = p.V1985F on NM_014903.6) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- NBPF26 | c.2640-1G>T p.X880_splice (on ENST00000620612; = p.X618_splice on NM_001351372.1) | Splice Site (SNP) | VAF 36/70 reads (51%) | called by muse, mutect2, varscan2
- NCKAP1L | c.1964A>G p.E655G | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NCKAP5L | c.274G>C p.D92H | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NDST4 | c.1672del p.H558Tfs*41 | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | called by mutect2, pindel, varscan2
- NEB | c.9141C>A p.H3047Q | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NEB | c.7213G>T p.E2405* | Nonsense Mutation (SNP) | VAF 21/68 reads (31%) | called by muse, mutect2, varscan2
- NEK10 | c.3350A>T p.N1117I | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.36); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- NES | c.2338C>T p.P780S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.15); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NEURL4 | c.4331T>C p.I1444T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- NFATC2 | c.1058G>T p.G353V | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NFYC | c.393G>C p.E131D | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- NIN | c.3637G>T p.D1213Y | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NIPSNAP3B | c.431-2A>T p.X144_splice | Splice Site (SNP) | VAF 32/43 reads (74%) | called by muse, mutect2, varscan2
- NLGN4X | c.1580G>T p.W527L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NLRP11 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NLRP14 | c.3086A>T p.E1029V | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- NLRP3 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- NLRP9 | c.13T>A p.F5I | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- NR1H4 | c.59G>T p.C20F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRG1 | c.1159_1160insT p.G387Vfs*7 (on ENST00000405005 / NM_013964.5; = p.G392Vfs*7 on NM_013956.5) | Frame Shift Ins (INS) | VAF 15/99 reads (15%) | called by mutect2, pindel, varscan2
- NRXN1 | c.484C>A p.L162M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.303); called by muse, mutect2
- NUB1 | c.220G>C p.E74Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NUDT7 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 60/91 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NUTM1 | c.2580del p.T861Hfs*38 | Frame Shift Del (DEL) | VAF 41/88 reads (47%) | called by mutect2, pindel, varscan2
- NXF5 | n.751+1G>T | Splice Site (SNP) | VAF 17/107 reads (16%) | called by mutect2, varscan2
- ODF2 | c.1087del p.L363Cfs*26 (on ENST00000434106 / NM_153433.2; = p.L339Cfs*26 on NM_002540.5 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- OLFML1 | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OLFML2B | c.1963G>C p.D655H | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
590 further variants in this file (249 protein-altering or splice-affecting, 305 silent, 36 other) are not listed here.
